Somatic mutation profile of tumor specimen TCGA-DJ-A4UR-01A (aliquot TCGA-DJ-A4UR-01A-11D-A257-08) from TCGA case TCGA-DJ-A4UR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 36.9 years (13,463 days).
Specimen TCGA-DJ-A4UR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0730dea2-cf7b-4e52-ad19-02853867cf98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4UR-10A (Blood Derived Normal), aliquot TCGA-DJ-A4UR-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/006f73cc-9f2b-4b12-9196-9443e8dae1a5

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 58/154 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CILP2 | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99364598; called by muse, mutect2, varscan2
- HUWE1 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53341208; called by muse, mutect2, varscan2
- MXRA5 | c.1760T>C p.I587T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs147548313, COSV99476626; called by muse, mutect2, varscan2
- NDRG4 | c.767C>A p.T256N (on ENST00000570248 / NM_001378344.1; = p.T288N on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99262000; called by muse, mutect2
- NKG7 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1372327663, COSV99389862; called by muse, mutect2, varscan2
- PCDHA1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as COSV100974347; called by muse, mutect2, varscan2
- PTPRA | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as rs375312168; called by muse, mutect2, varscan2
- TENM1 | c.3832G>T p.V1278L | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as COSV100949774; called by muse, mutect2
- ADAMTSL2 | c.2660T>A p.V887D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FYCO1 | c.2547G>T p.S849= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99945558; called by muse, mutect2, varscan2
- LRFN5 | c.75C>A p.V25= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99983368; called by muse, mutect2, varscan2
- TMEM260 | c.1366T>C p.L456= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1395997834, COSV99840251; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505434 T>C | 5'Flank (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2
- TMEM183B | n.321C>A | RNA (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
